Somatic mutation profile of tumor specimen TCGA-63-A5MY-01A (aliquot TCGA-63-A5MY-01A-11D-A26M-08) from TCGA case TCGA-63-A5MY, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-A5MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23fc7fa5-bfe3-4aa3-b160-a17da62b761a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MY-10A (Blood Derived Normal), aliquot TCGA-63-A5MY-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c7a5525-91f0-430f-b106-58ce1ed4e0ab

The open-access MAF lists 187 somatic variants for this specimen: 135 protein-altering or splice-affecting, 46 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 46, Nonsense Mutation 10, Frame Shift Del 5, Intron 3, RNA 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 12/13 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADGRB3 | c.2624G>A p.G875D | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); catalogued as rs1452631834, COSV53237967; called by muse, mutect2, varscan2
- ADGRB3 | c.2870G>T p.C957F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99483411; called by muse, mutect2, varscan2
- AHNAK2 | c.13263C>A p.N4421K | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV100315416; called by muse, mutect2, varscan2
- AHNAK2 | c.9379G>A p.G3127R | Missense Mutation (SNP) | VAF 155/234 reads (66%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV100315420; called by mutect2, varscan2
- AMY2B | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796169; called by muse, mutect2, varscan2
- ANKEF1 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as COSV101000978; called by muse, mutect2, varscan2
- ANKRD26 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1223425535, COSV101062909; called by muse, mutect2, varscan2
- ANKRD6 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100329394; called by muse, mutect2
- ANO3 | c.1466T>A p.F489Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99880263; called by muse, mutect2, varscan2
- APOB | c.4192G>T p.D1398Y | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99263441; called by muse, mutect2, varscan2
- ARHGAP35 | c.3994C>A p.L1332M | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101350684, COSV101351938; called by muse, mutect2, varscan2
- AXL | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99995846; called by muse, mutect2, varscan2
- B3GAT1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100437710, COSV56999527; called by muse, mutect2, varscan2
- BPIFB6 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100848480; called by muse, mutect2, varscan2
- CCDC33 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs780371171, COSV99165864; called by muse, mutect2, varscan2
- CEL | c.972C>G p.I324M (on ENST00000673714; = p.I321M on NM_001807.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100672215; called by muse, mutect2, varscan2
- CEP290 | c.5284C>T p.R1762C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs373307908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP100 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs779987447, COSV100729061; called by muse, mutect2, varscan2
- CHST1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV100345953; called by muse, mutect2
- CLP1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100239702; called by muse, mutect2, varscan2
- CNST | c.1067G>C p.G356A | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV63621548; called by muse, mutect2, varscan2
- CNTN3 | c.440del p.P147Hfs*52 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1160186744; called by mutect2, pindel, varscan2
- COL5A2 | c.3148G>T p.G1050C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879992; called by muse, mutect2, varscan2
- COL5A2 | c.3148-1G>T p.X1050_splice | Splice Site (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100879993; called by muse, mutect2, varscan2
- COPS2 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100157094; called by muse, mutect2, varscan2
- CTNND2 | c.3335C>G p.A1112G | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100471382; called by muse, mutect2, varscan2
- DGKB | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV51791498, COSV99336204; called by muse, mutect2, varscan2
- DHX16 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV100905130; called by muse, mutect2, varscan2
- DNA2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV100622349; called by muse, mutect2, varscan2
- EML1 | c.75C>G p.S25R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99214486; called by muse, mutect2, varscan2
- FAM71F2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101100651; called by muse, mutect2, varscan2
- FAT4 | c.12680G>T p.R4227L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV58675438; called by muse, mutect2, varscan2
- FBN1 | c.3124G>T p.G1042C | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM085409, COSV100353947, COSV57316029; called by muse, mutect2, varscan2
- FSCN2 | c.153C>G p.D51E | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV100603238; called by muse, mutect2, varscan2
- GEMIN5 | c.3455C>A p.T1152N | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV53564105, COSV99593566; called by muse, mutect2, varscan2
- GLI2 | c.3887C>A p.P1296Q (on ENST00000361492 / NM_001374353.1; = p.P1313Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.038); catalogued as COSV100082251; called by muse, mutect2, varscan2
- HDAC9 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as COSV101286088; called by muse, mutect2, varscan2
- HECW1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | catalogued as COSV101222774; called by muse, mutect2, varscan2
- HELLS | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99491703; called by muse, mutect2, varscan2
- HGF | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV99735502; called by muse, mutect2, varscan2
- HOXA2 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as COSV56066750; called by muse, mutect2, varscan2
- HTR1E | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540916, COSV59507323; called by muse, mutect2, varscan2
- IGKV2D-24 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1247896098; called by muse, mutect2, varscan2
- INPP5D | c.2738C>A p.P913H (on ENST00000445964 / NM_001017915.3; = p.P912H on NM_005541.5) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100856502; called by muse, mutect2, varscan2
- JHY | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99912694; called by muse, mutect2, varscan2
- KANK4 | c.2185del p.Q729Rfs*30 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as COSV100443080; called by mutect2, pindel, varscan2
- KANSL3 | c.1259G>C p.R420P | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100830877, COSV62615683; called by muse, mutect2, varscan2
- KCNA6 | c.1319C>G p.S440W | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54974145, COSV54975714, COSV99768309; called by muse, mutect2, varscan2
- KCNV1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.289); catalogued as COSV99818853; called by muse, mutect2, varscan2
- KIAA1958 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100515823; called by muse, mutect2, varscan2
- KIF15 | c.3191A>T p.D1064V | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100392422; called by muse, mutect2, varscan2
- KIF26A | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100180710; called by muse, mutect2, varscan2
- LCN9 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52991232, COSV99479481; called by muse, mutect2, varscan2
- LRIT1 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV100927994; called by muse, mutect2, varscan2
- LRP1B | c.11954G>A p.W3985* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV67232700, COSV67256675; called by muse, mutect2, varscan2
- MAGEA12 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 98/111 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1365083658, COSV100756793; called by muse, mutect2, varscan2
- MATK | c.1195G>T p.G399W (on ENST00000310132 / NM_139355.3; = p.G400W on NM_002378.4) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100035821; called by muse, mutect2, varscan2
- MBOAT1 | c.1031T>A p.M344K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV100208352; called by muse, mutect2, varscan2
- MICAL3 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.628); catalogued as rs761008920, COSV99259756; called by muse, mutect2, varscan2
- MRPS34 | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV99167647; called by muse, mutect2
- MYO7A | c.3397G>T p.G1133W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101289033, COSV68683619; called by muse, mutect2, varscan2
- NFE2L2 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101229293, COSV67963123; called by muse, mutect2, varscan2
- NKD2 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760177567, COSV99723772; called by muse, mutect2, varscan2
- NLGN4X | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99319724, COSV99323108; called by muse, varscan2
- NLRP12 | c.1524G>T p.R508S | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV100144805; called by muse, mutect2, varscan2
- NLRP5 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101173343; called by muse, mutect2, varscan2
- NLRP7 | c.2364C>G p.N788K (on ENST00000340844 / NM_206828.3; = p.N760K on NM_139176.3) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60176316; called by muse, mutect2, varscan2
- NPAS2 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1320681351, COSV59560351; called by muse, mutect2, varscan2
- NTS | c.438T>A p.Y146* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99754889; called by muse, mutect2, varscan2
- OAS3 | c.1632C>G p.S544R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV99966021; called by muse, mutect2, varscan2
- OR1M1 | c.916A>T p.N306Y | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.58); PolyPhen benign (0.205); catalogued as COSV101447536; called by muse, mutect2, varscan2
- OR2A2 | c.420C>A p.C140* | Nonsense Mutation (SNP) | VAF 58/109 reads (53%) | catalogued as rs1231624131, COSV101286617; called by muse, mutect2, varscan2
- OR4D9 | c.500C>G p.P167R | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs747489275, COSV100259694; called by muse, mutect2, varscan2
- OR8A1 | c.710T>A p.F237Y | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV99420288; called by muse, mutect2, varscan2
- PCLO | c.5337G>C p.L1779F | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV100427144, COSV61636666; called by muse, mutect2, varscan2
- PDE1A | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100112830; called by muse, mutect2, varscan2
- PDGFRA | c.550G>C p.V184L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99955392; called by muse, mutect2, varscan2
- PLCH1 | c.1070T>G p.V357G (on ENST00000340059 / NM_001130960.2; = p.V369G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100395496; called by muse, mutect2, varscan2
- PLXNA4 | c.5179C>A p.H1727N | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100322352; called by muse, mutect2, varscan2
- PLXNB2 | c.4499G>T p.R1500L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100833843; called by muse, mutect2, varscan2
- PPP3CA | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV100547302; called by muse, mutect2, varscan2
- PRG3 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99755767; called by muse, mutect2, varscan2
- PRSS12 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs751693086, COSV99627685; called by muse, mutect2, varscan2
- PTPRB | c.4910T>C p.V1637A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99715639; called by muse, mutect2, varscan2
- PTPRB | c.3796C>T p.L1266F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.516); catalogued as COSV99715640, COSV99717087; called by muse, mutect2, varscan2
- PTPRT | c.2101T>C p.Y701H | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780476265, COSV100625007; called by muse, mutect2, varscan2
- PVRIG | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 40/125 reads (32%) | catalogued as COSV99443670; called by muse, mutect2, varscan2
- QPCT | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | catalogued as COSV100621510; called by muse, mutect2, varscan2
- RBBP5 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99196738; called by muse, mutect2, varscan2
- RPS6KA4 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99589760; called by muse, mutect2, varscan2
- RYR2 | c.13216A>C p.M4406L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100767641; called by muse, mutect2, varscan2
- SCARF1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1280340427, COSV99556831; called by muse, mutect2, varscan2
- SCN10A | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101479232; called by muse, mutect2, varscan2
- SDS | c.267C>G p.S89R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99980913; called by muse, mutect2
- SENP6 | c.2266A>G p.I756V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV64190948; called by muse, mutect2, varscan2
- SETDB1 | c.2372T>C p.M791T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.968); catalogued as rs1404775873, COSV99643687; called by muse, mutect2, varscan2
- SF3A1 | c.1789A>T p.M597L | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99305177; called by muse, mutect2, varscan2
- SIDT1 | c.1950G>T p.M650I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99333086; called by muse, mutect2, varscan2
- SIPA1L3 | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV55925224; called by muse, mutect2, varscan2
- SLC39A12 | c.1285A>T p.K429* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV101069826; called by muse, mutect2, varscan2
- SLC6A5 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100116392; called by muse, mutect2, varscan2
- SND1 | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100689643; called by muse, mutect2, varscan2
- SOX3 | c.508A>C p.S170R | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100983649; called by muse, mutect2, varscan2
- SPTB | c.6588G>C p.K2196N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100731081; called by muse, mutect2, varscan2
- TAAR8 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV99257046; called by muse, mutect2, varscan2
- TACR3 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.121); catalogued as COSV100510053; called by muse, mutect2, varscan2
- TBR1 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101271396; called by muse, mutect2, varscan2
- TEK | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101193110; called by muse, mutect2, varscan2
- TENT5C | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV101032748; called by muse, mutect2, varscan2
- TERT | c.3340G>T p.A1114S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99716196; called by muse, mutect2, varscan2
- THSD7B | c.1880C>A p.T627N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV99743940; called by muse, mutect2
- TMEM132D | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV101396280; called by muse, mutect2, varscan2
- TNR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs138654492; called by muse, mutect2, varscan2
- TRIM21 | c.1322C>G p.P441R | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV54346189, COSV99587465; called by muse, mutect2, varscan2
- TRIM3 | c.1529T>C p.I510T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100624224; called by muse, mutect2, varscan2
- TTLL7 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53085911; called by muse, mutect2, varscan2
- TUBA3C | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101262747; called by muse, mutect2
- UFL1 | c.1957G>C p.V653L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100990005; called by muse, mutect2, varscan2
- ULK1 | c.2756A>T p.D919V | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV100416479; called by muse, mutect2, varscan2
- USP26 | c.2421A>T p.K807N | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.407); catalogued as COSV100896534; called by muse, mutect2, varscan2
- USP29 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99517616; called by muse, mutect2, varscan2
- USP30 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99980107; called by muse, mutect2, varscan2
- UTP20 | c.80A>T p.N27I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99880731; called by muse, mutect2, varscan2
- VN1R4 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV100237313, COSV60804607; called by muse, mutect2, varscan2
- ZIC1 | c.461C>A p.A154E | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV99291477, COSV99292620; called by muse, mutect2, varscan2
- ZMYM1 | c.1136T>A p.V379D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100720891; called by muse, mutect2, varscan2
- ZNF521 | c.3239T>C p.L1080P | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100831386; called by muse, mutect2, varscan2
- ZNF547 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.055); catalogued as COSV99987735; called by muse, mutect2, varscan2
- ZNF813 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV67178368; called by muse, mutect2
- CCDC15 | c.937del p.E313Kfs*25 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- ERC1 | c.449_450del p.T150Nfs*16 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by pindel, varscan2
- IGKV6D-41 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRRC3B | c.392del p.N131Mfs*6 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- PCMTD1 | c.757C>A p.R253S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AGPAT4 | c.309G>T p.L103= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV100210933; called by muse, mutect2, varscan2
- ALK | c.2937G>T p.V979= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as COSV101201129; called by muse, mutect2, varscan2
- AMY2B | c.1122G>A p.G374= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as rs761315415, COSV100796171; called by muse, mutect2, varscan2
- APC2 | c.1803C>T p.G601= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs746930193, COSV99279121; called by muse, mutect2
- ARAP1 | c.1869C>T p.P623= (on ENST00000393609 / NM_001040118.2; = p.P378= on NM_015242.4) | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100501527; called by muse, mutect2
- ASCL3 | c.141C>T p.S47= | Silent (SNP) | VAF 91/124 reads (73%) | catalogued as COSV100366820; called by muse, mutect2, varscan2
- CELSR3 | c.912C>A p.A304= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV99372476; called by muse, mutect2, varscan2
- COL22A1 | c.4260C>G p.G1420= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100276194; called by muse, mutect2, varscan2
- CRB1 | c.2325G>C p.L775= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100957649; called by muse, mutect2, varscan2
- CREG2 | c.474C>A p.P158= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs748123128, COSV100240319; called by muse, mutect2, varscan2
- CSMD3 | c.789C>T p.N263= | Silent (SNP) | VAF 44/54 reads (81%) | catalogued as COSV99823822; called by muse, mutect2, varscan2
- CSRP2 | c.495C>T p.I165= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1317043136, COSV100222631; called by muse, mutect2
- E2F8 | c.2370A>G p.P790= | Silent (SNP) | VAF 63/98 reads (64%) | catalogued as COSV100001272; called by muse, mutect2, varscan2
- GABRR3 | c.1200T>G p.S400= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV101512254; called by muse, mutect2, varscan2
- GAS2 | c.399G>C p.S133= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV53413005, COSV99534642; called by muse, mutect2, varscan2
- GET4 | c.909C>T p.T303= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs775630074, COSV99762742; called by muse, mutect2, varscan2
- HCN1 | c.2289G>A p.P763= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs759408275, COSV57502023; called by muse, mutect2, varscan2
- KIAA1210 | c.3075C>A p.S1025= | Silent (SNP) | VAF 88/107 reads (82%) | catalogued as COSV101273906; called by muse, mutect2, varscan2
- KLHDC7A | c.1773G>A p.L591= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV101272709; called by muse, mutect2, varscan2
- KLHL14 | c.1276T>C p.L426= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100839050; called by muse, mutect2, varscan2
- KMT2D | c.3702G>T p.G1234= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs1187018461, COSV99977320; called by muse, mutect2, varscan2
- KPRP | c.831C>A p.P277= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV100908657; called by muse, mutect2, varscan2
- LRRCC1 | c.771C>T p.P257= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100835279; called by muse, mutect2, varscan2
- MDN1 | c.600G>A p.E200= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101020740; called by muse, mutect2, varscan2
- OR2J2 | c.846C>A p.V282= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV101013272; called by muse, mutect2, varscan2
- OR4D5 | c.603T>A p.S201= | Silent (SNP) | VAF 64/171 reads (37%) | catalogued as COSV100189716; called by muse, mutect2, varscan2
- OR52H1 | c.126G>T p.V42= (on ENST00000322653; = p.V48= on NM_001005289.1) | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV100497244; called by muse, mutect2, varscan2
- PGA5 | c.1050C>T p.G350= | Silent (SNP) | VAF 51/138 reads (37%) | catalogued as COSV100409260; called by muse, mutect2, varscan2
- PHIP | c.3771A>G p.L1257= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99243354; called by muse, mutect2, varscan2
- PON1 | c.216T>G p.P72= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99731951; called by muse, mutect2, varscan2
- POU6F2 | c.249T>C p.S83= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV101302421; called by muse, mutect2, varscan2
- PREX2 | c.4497A>G p.A1499= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as COSV99904804; called by muse, mutect2, varscan2
- RRAD | c.744G>A p.V248= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV100233633; called by muse, mutect2, varscan2
- SHANK1 | c.4464G>A p.L1488= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV99520141; called by muse, mutect2, varscan2
- SIGLEC11 | c.1008G>T p.A336= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV101389042, COSV70222174; called by muse, mutect2, varscan2
- SPPL2C | c.123G>T p.L41= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100233923; called by muse, mutect2, varscan2
- ST7L | c.1293G>A p.L431= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs200916447, COSV100573617; called by muse, mutect2, varscan2
- TANC2 | c.2928G>A p.T976= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1299146457, COSV67335615; called by muse, mutect2, varscan2
- TBXAS1 | c.747C>T p.D249= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as rs1331998348, COSV99694727; called by muse, mutect2, varscan2
- TENT4A | c.1815A>C p.S605= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as COSV100048582; called by muse, mutect2, varscan2
- TGFBRAP1 | c.942A>G p.E314= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV99304685; called by muse, mutect2, varscan2
- TMCC2 | c.855C>T p.T285= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs768405452, COSV100319142; called by muse, mutect2, varscan2
- TMEM151A | c.393C>T p.D131= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs779025990, COSV100516807; called by muse, mutect2, varscan2
- TOP1 | c.1384C>A p.R462= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100793661; called by muse, mutect2, varscan2
- TRIM50 | c.1035C>A p.S345= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV99392185; called by muse, mutect2, varscan2
- VCPKMT | c.216G>T p.L72= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV53571799; called by muse, mutect2, varscan2
- KIR3DX1 | n.560G>T | RNA (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99682913; called by muse, mutect2, varscan2
- NEDD8 | chr14:24213492 T>G | 3'Flank (SNP) | VAF 40/84 reads (48%) | catalogued as COSV99164589; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2032G>C | Intron (SNP) | VAF 28/60 reads (47%) | catalogued as COSV56887113, COSV99194577; called by muse, mutect2, varscan2
- PPP3CB | c.1187-2114G>T | Intron (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- SSX9P | n.71A>T | RNA (SNP) | VAF 117/147 reads (80%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3130G>T | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as rs558050239, COSV100954109; called by muse, mutect2
